Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43J, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43J-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Odontophagia with esophageal mass. Clinical Diagnosis: Carcinoma on
Operative Procedure: Transhiatal esophagectomy with CEGA.

PROCEDURE: SPGD

VERIFIED BY:

1. "Proximal stomach distal esophagus freeze proximal margin" A 2.5 x 1.7 cm mid esophageal tumor arising 6.0 cm from proximal margin. Overall, the segment is 15.3 cm of which 10.8 cm is esophageal and 4.2 cm is gastric. The firm, ulcerated mass has a gray-tan, firm cut surface with a maximum thickness of 0.9 cm. There is penetration to within less than 0.1 cm of the adventitia. The mucosa that is distal to the firm mass is purple-gray with some loss of mucosal fold. The mucosa and submucosa proximal to the ulcerated mass is focally hemorrhagic. The esophagogastric junction has unremarkable mucosa and the gastric mucosa is focally bosselated with no mass in the gastric mucosa. Retrieved from the fatty tissue are lymph node candidates up to 0.7 cm in greatest dimension.

1A. Proximal margin. Frozen section control in one cassette.

1B-C. Tumor to proximal mucosa.

1D-E. Tumor to distal mucosa.

1F. EG junction and gastric mucosa.

1G. Three whole lymph node candidates. Fat retained.

FROZEN SECTION REPORT

1. Negative for carcinoma.

I, have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

1C120-3

~~Gleason~~

PROCEDURE: SPMI

VERIFIED BY:

Carcinoma, squamous
cell, NOS
807013

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA, CARCINOMA

LOCATION: Middle esophagus.

SIZE: 2.5 cm.

HAS IT BEEN TREATED PREOPERATIVE WITH CHEMO/RADIATION THERAPY?: No.

TYPE OF CARCINOMA: Squamous cell carcinoma, typical.

DEPTH OF INVASION: Adventitia/perigastric adipose.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/3

Site:
esophagus, middle
third c15.4

8-20-12 RD

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE:

REQ DOC: [REDACTED]

DISTANT METASTASIS: Unknown.

DISTAL MARGIN INVOLVED: No.

pT3 NO

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. Esophagus, resection: Invasive poorly differentiated squamous cell carcinoma (2.5 cm) invading into adventitia. Margins free. focal perineural and vascular invasion identified. Three benign lymph nodes (0/3). Please see template for details.

[REDACTED]

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

8/9/12

Source: NCI Genomic Data Commons file f708061c-4648-401e-95b4-6cc409175583 (TCGA-L5-A43J.3C212325-D788-44B0-8D6C-292F2FAC7487.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).